Somatic mutation profile of tumor specimen TCGA-14-0871-01A (aliquot TCGA-14-0871-01A-01D-1492-08) from TCGA case TCGA-14-0871, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 75.0 years (27,387 days).
Specimen TCGA-14-0871-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2d0b5003-ffff-4c0f-9065-911d581195c4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-14-0871-10A (Blood Derived Normal), aliquot TCGA-14-0871-10A-01D-1492-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d7b171dc-eafe-43da-8df6-a909cfd362b2

The open-access MAF lists 56 somatic variants for this specimen: 46 protein-altering or splice-affecting, 10 silent.
By variant classification: Missense Mutation 39, Silent 10, Nonsense Mutation 5, Frame Shift Ins 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DICER1 | c.5438A>G p.E1813G | Missense Mutation (SNP) | VAF 474/497 reads (95%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58615258, COSV58615306, COSV58615741; called by muse, mutect2, varscan2
- AKTIP | c.619C>T p.Q207* | Nonsense Mutation (SNP) | VAF 6/116 reads (5%) | catalogued as COSV50873744; called by muse, mutect2
- ANK2 | c.10145T>C p.I3382T | Missense Mutation (SNP) | VAF 11/230 reads (5%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0); catalogued as COSV52150434; called by muse, mutect2
- C3orf38 | c.519G>A p.W173* | Nonsense Mutation (SNP) | VAF 145/223 reads (65%) | catalogued as COSV59627722; called by muse, mutect2, varscan2
- CCDC178 | c.1075A>T p.I359L | Missense Mutation (SNP) | VAF 136/256 reads (53%) | SIFT tolerated (0.16); PolyPhen benign (0.012); catalogued as COSV55763950; called by muse, mutect2, varscan2
- CPO | c.600A>T p.Q200H | Missense Mutation (SNP) | VAF 224/279 reads (80%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as COSV55938951; called by muse, mutect2, varscan2
- CTSF | c.613C>G p.R205G | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0.08); catalogued as COSV59747781; called by muse, mutect2, varscan2
- DRD3 | c.1007G>A p.G336E | Missense Mutation (SNP) | VAF 99/196 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55679149, COSV55679958; called by muse, mutect2, varscan2
- FANCM | c.1031A>T p.N344I | Missense Mutation (SNP) | VAF 93/95 reads (98%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as rs754308697, COSV57498269; called by muse, mutect2, varscan2
- FIGN | c.1681G>A p.G561R | Missense Mutation (SNP) | VAF 35/185 reads (19%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.993); catalogued as rs367860574; called by muse, mutect2, varscan2
- FUCA1 | c.598G>A p.G200S | Missense Mutation (SNP) | VAF 88/145 reads (61%) | SIFT tolerated (0.32); PolyPhen benign (0.068); catalogued as rs1170852060, COSV65698786; called by muse, varscan2
- GIMAP2 | c.874C>T p.H292Y | Missense Mutation (SNP) | VAF 16/208 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1453323403, COSV56234689; called by muse, mutect2
- GIMAP5 | c.884T>A p.L295H | Missense Mutation (SNP) | VAF 59/192 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.253); catalogued as COSV57529761, COSV57529909; called by muse, mutect2, varscan2
- GPC6 | c.815A>G p.N272S | Missense Mutation (SNP) | VAF 288/300 reads (96%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1360308566, COSV65502385; called by muse, mutect2, varscan2
- KCTD15 | c.98C>T p.T33I | Missense Mutation (SNP) | VAF 40/359 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.649); catalogued as COSV52289190; called by muse, mutect2, varscan2
- KIAA1958 | c.359G>T p.C120F | Missense Mutation (SNP) | VAF 9/191 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV61722109; called by muse, mutect2
- KRTAP10-9 | c.662C>A p.T221N | Missense Mutation (SNP) | VAF 55/525 reads (10%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.991); catalogued as COSV59954656; called by muse, mutect2, varscan2
- LRRC41 | c.2050G>C p.E684Q | Missense Mutation (SNP) | VAF 48/340 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.909); catalogued as rs758108659, COSV58439182; called by muse, mutect2, varscan2
- MFSD9 | c.543C>G p.I181M | Missense Mutation (SNP) | VAF 83/448 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV51492902; called by muse, mutect2, varscan2
- MTRR | c.371G>A p.G124D (on ENST00000264668; = p.G97D on NM_002454.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 44/271 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52942225; called by muse, mutect2, varscan2
- NF1 | c.3049C>T p.Q1017* | Nonsense Mutation (SNP) | VAF 68/72 reads (94%) | catalogued as CM950846, COSV62195945; called by muse, mutect2, varscan2
- NOX5 | c.2069T>A p.L690Q | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV52985960; called by muse, mutect2, varscan2
- NR5A2 | c.875G>C p.S292T (on ENST00000367362 / NM_205860.3; = p.S246T on NM_003822.5) | Missense Mutation (SNP) | VAF 110/255 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52646436; called by muse, mutect2, varscan2
- NRXN1 | c.1832A>T p.D611V | Missense Mutation (SNP) | VAF 137/181 reads (76%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); catalogued as COSV58440676; called by muse, mutect2, varscan2
- NUP62CL | c.311C>G p.A104G | Missense Mutation (SNP) | VAF 39/191 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV65235458; called by muse, mutect2, varscan2
- OR2T3 | c.580T>C p.C194R | Missense Mutation (SNP) | VAF 373/667 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369559398; called by muse, mutect2, varscan2
- OR5AR1 | c.203T>G p.F68C | Missense Mutation (SNP) | VAF 156/472 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.387); catalogued as COSV57253083; called by muse, mutect2, varscan2
- PCYT1A | c.519T>G p.Y173* | Nonsense Mutation (SNP) | VAF 33/184 reads (18%) | catalogued as COSV53056525; called by muse, mutect2, varscan2
- PTPRD | c.4300G>A p.E1434K | Missense Mutation (SNP) | VAF 33/117 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV61932965, COSV61935427; called by muse, mutect2, varscan2
- RAB24 | c.434A>G p.N145S | Missense Mutation (SNP) | VAF 66/155 reads (43%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs755530764, COSV57462923; called by muse, mutect2, varscan2
- SLC28A3 | c.159T>A p.D53E | Missense Mutation (SNP) | VAF 44/183 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV66152303; called by muse, mutect2, varscan2
- SLC2A14 | c.1195G>T p.A399S | Missense Mutation (SNP) | VAF 40/72 reads (56%) | SIFT tolerated (0.3); PolyPhen benign (0.349); catalogued as COSV61585777; called by muse, mutect2, varscan2
- SYNE1 | c.2528G>C p.R843P (on ENST00000367255 / NM_182961.4; = p.R850P on NM_033071.3) | Missense Mutation (SNP) | VAF 21/171 reads (12%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV54927660; called by muse, mutect2, varscan2
- TMEM132B | c.2488G>T p.E830* | Nonsense Mutation (SNP) | VAF 21/100 reads (21%) | catalogued as COSV54747361, COSV54774585; called by muse, mutect2, varscan2
- TP53 | c.902dup p.G302Rfs*4 | Frame Shift Ins (INS) | VAF 96/143 reads (67%) | catalogued as COSV53177081; called by mutect2, pindel, varscan2
- TRHDE | c.359C>T p.T120M | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs776708481, COSV53836654; called by muse, mutect2
- TTBK1 | c.2020G>T p.G674C | Missense Mutation (SNP) | VAF 96/287 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV52489079; called by muse, mutect2, varscan2
- TUBG2 | c.700A>G p.T234A | Missense Mutation (SNP) | VAF 29/139 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as rs1157142160, COSV52216984; called by muse, mutect2, varscan2
- WDR88 | c.1023T>A p.F341L | Missense Mutation (SNP) | VAF 210/650 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.371); catalogued as COSV63450871; called by muse, mutect2, varscan2
- WIF1 | c.708C>A p.F236L | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.127); catalogued as COSV54130211; called by muse, mutect2, varscan2
- WNK4 | c.1814C>A p.P605H | Missense Mutation (SNP) | VAF 30/109 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV55902241; called by muse, mutect2, varscan2
- WWP2 | c.2600T>C p.F867S | Missense Mutation (SNP) | VAF 26/28 reads (93%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63123767; called by muse, mutect2, varscan2
- XKR5 | c.586A>T p.S196C | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.551); catalogued as COSV68398032; called by muse, mutect2, varscan2
- GAS2L2 | c.1877G>C p.R626T | Missense Mutation (SNP) | VAF 222/240 reads (93%) | SIFT tolerated (0.26); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- MARCHF6 | c.2295dup p.G766Wfs*25 | Frame Shift Ins (INS) | VAF 12/100 reads (12%) | called by mutect2, pindel, varscan2
- UBE2NL | c.284A>T p.K95M | Missense Mutation (SNP) | VAF 130/138 reads (94%) | SIFT deleterious (0); PolyPhen possibly damaging (0.54); called by muse, mutect2, varscan2
- ACTN1 | c.1785C>T p.I595= | Silent (SNP) | VAF 19/138 reads (14%) | catalogued as COSV51989211; called by muse, mutect2, varscan2
- ARHGAP25 | c.1176T>C p.S392= (on ENST00000409202 / NM_001007231.3; = p.S384= on NM_014882.3) | Silent (SNP) | VAF 48/234 reads (21%) | catalogued as COSV54899894; called by muse, mutect2, varscan2
- CENPU | c.756T>C p.N252= | Silent (SNP) | VAF 46/115 reads (40%) | catalogued as rs1396758809, COSV55656760; called by muse, mutect2, varscan2
- GABRQ | c.222G>A p.L74= | Silent (SNP) | VAF 14/229 reads (6%) | catalogued as rs1556818218, COSV64781131; called by muse, mutect2
- IFI16 | c.471C>G p.A157= | Silent (SNP) | VAF 26/177 reads (15%) | catalogued as COSV55530609, COSV55531905; called by muse, mutect2, varscan2
- LMAN2L | c.387C>G p.G129= | Silent (SNP) | VAF 42/542 reads (8%) | catalogued as COSV53840813; called by muse, mutect2
- OSBP | c.765C>T p.I255= | Silent (SNP) | VAF 72/266 reads (27%) | catalogued as rs781114937, COSV55661287, COSV55664519; called by muse, mutect2, varscan2
- UBE2NL | c.285G>A p.K95= | Silent (SNP) | VAF 132/140 reads (94%) | called by muse, mutect2, varscan2
- URI1 | c.159G>A p.K53= | Silent (SNP) | VAF 152/524 reads (29%) | catalogued as COSV56348447; called by muse, mutect2, varscan2
- ZNF470 | c.660A>G p.Q220= | Silent (SNP) | VAF 22/136 reads (16%) | catalogued as COSV57967937; called by muse, mutect2, varscan2
